Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1M6, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1M6-01A (Primary Tumor).

ICD-0-3
Carcinoma, squamous cell, NOS
Site: CERVIX, NOS C53.9 2/24/11 Jm

SURGICAL PATHOLOGY REPORT - COI

Patient Name: [REDACTED]
Address: [REDACTED]
Gender: F
DOB: [REDACTED]

Service: Inside/Outside
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Accession #: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

Physician(s): [REDACTED] M.D.

DIAGNOSIS

UTERUS, CERVIX, BIOPSY

- SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

M.D.

***Report Electronically Reviewed and Signed Out By

.D.***

Microscopic Description and Comment

I agree with [REDACTED] that the cervical biopsy shows a poorly differentiated squamous cell carcinoma. The tumor invades fibrotic, focally calcified stroma. There is focal necrosis.

History

The patient is a [REDACTED] year old woman.

Material(s) Received

Submitted by [REDACTED] for review is 1 slide labeled [REDACTED] accompanied by a corresponding pathology report. The material originates from [REDACTED] (1)

Physician Copy -
END OF REPORT

IIHAA Discrepancy		X

Source: NCI Genomic Data Commons file 5942a8ec-6ab7-4e10-989a-3d70e9a62bad (TCGA-C5-A1M6.849F2BBF-C820-4C31-B213-648545060C3E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).